Gene-level copy-number profile of specimen HCM-WCMC-1285-C54-85A from HCMI case HCM-WCMC-1285-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 34.0 years (12,423 days).
Specimen HCM-WCMC-1285-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7684d206-c9e6-4690-93ce-cdc898baa973.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1285-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/c251636f-25aa-498b-9c18-02076436a117

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,371; copy number 1: 339; copy number 2: 50,787; copy number 3: 3,802; copy number 4: 1,105.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,932,238, 8 genes (within-gene range 0–2): LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901.
- chr4:105,959–499,156, 19 genes: AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
